Somatic mutation profile of tumor specimen TCGA-EK-A2R7-01A (aliquot TCGA-EK-A2R7-01A-11D-A18J-09) from TCGA case TCGA-EK-A2R7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 45.1 years (16,487 days).
Specimen TCGA-EK-A2R7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a09007ef-5d74-46d3-ae24-49c9ca2ca75e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2R7-10A (Blood Derived Normal), aliquot TCGA-EK-A2R7-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4067f9a-b8ec-4fa3-a3f7-4061e87c9bbc

The open-access MAF lists 138 somatic variants for this specimen: 106 protein-altering or splice-affecting, 25 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 25, Nonsense Mutation 12, Intron 3, RNA 2, 3'Flank 2, Splice Site 2, Frame Shift Del 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD4 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100084495, COSV53992697; called by muse, mutect2, varscan2
- ADGRV1 | c.14365C>T p.R4789W | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1131691924, CM122137, COSV67978552; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AGPS | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV51564806; called by muse, mutect2, varscan2
- AGTPBP1 | c.793A>G p.N265D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV61272362; called by muse, mutect2, varscan2
- AKAP11 | c.5491C>T p.Q1831* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV50297394; called by muse, mutect2
- ATP13A1 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs563912098, COSV52286714, COSV52291875; called by muse, mutect2, varscan2
- ATRX | c.5413C>A p.H1805N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64877552; called by muse, mutect2, varscan2
- BTBD7 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1208202747, COSV58286545; called by muse, mutect2, varscan2
- C12orf40 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV61133086; called by muse, mutect2, varscan2
- C2CD4B | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.137); catalogued as COSV66791068; called by muse, varscan2
- CARF | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as COSV57547898; called by muse, mutect2, varscan2
- CD177 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.511); catalogued as COSV100945878; called by muse, mutect2, varscan2
- CENPF | c.4349C>G p.S1450* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100871571; called by muse, mutect2
- COL11A1 | c.2803C>A p.P935T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV62182128, COSV62188258; called by muse, mutect2
- COL25A1 | c.360C>A p.C120* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | catalogued as COSV101211272; called by muse, mutect2
- DDHD2 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68157995; called by muse, mutect2
- DMTN | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV56112803; called by muse, varscan2
- DNAH10 | c.12197C>G p.S4066C (on ENST00000409039; = p.S4005C on NM_207437.3) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV101292093; called by muse, mutect2
- DYNC1H1 | c.8940G>C p.L2980F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64137027; called by muse, mutect2, varscan2
- DYNC2H1 | c.3554C>T p.S1185L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV62095597; called by muse, mutect2, varscan2
- ENPEP | c.1762G>C p.D588H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV54451985; called by muse, mutect2, varscan2
- EPHA4 | c.2414G>A p.S805N | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1273295450, COSV56034863; called by muse, mutect2, varscan2
- ETV5 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60502867; called by muse, mutect2, varscan2
- FAM126B | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV53772917; called by muse, mutect2, varscan2
- FAM71C | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60942684, COSV60943367; called by muse, mutect2, varscan2
- FANCB | c.1635A>G p.I545M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV60760121; called by muse, mutect2, varscan2
- FASTKD5 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1234915501, COSV53906403; called by muse, mutect2, varscan2
- FBXW4 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as rs199576249; called by mutect2, varscan2
- FBXW7 | c.1798G>C p.D600H (on ENST00000281708 / NM_001349798.2; = p.D520H on NM_018315.5) | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55921359, COSV55925782, COSV55951044; called by muse, mutect2, varscan2
- FTCD | c.862_864del p.K288del | In Frame Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1321726682; called by mutect2, pindel, varscan2
- FUT6 | c.23A>T p.K8M | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV54606270; called by muse, mutect2, varscan2
- GOLGA3 | c.1667C>A p.T556K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99202340; called by muse, mutect2, varscan2
- GRIK5 | c.244+2T>C p.X82_splice | Splice Site (SNP) | VAF 29/105 reads (28%) | catalogued as COSV53479446; called by muse, mutect2, varscan2
- HARS1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100297924; called by muse, mutect2
- HEATR5A | c.4984G>T p.E1662* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV66341617; called by muse, mutect2
- HOMER1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV56526569; called by muse, mutect2, varscan2
- HPRT1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV53777207; called by muse, mutect2, varscan2
- HSD3B1 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs1464114498, COSV52490861; called by muse, mutect2, varscan2
- IFT57 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV52709982; called by muse, mutect2, varscan2
- IGSF8 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58758217; called by muse, mutect2, varscan2
- IPO7 | c.1564C>G p.Q522E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63352682; called by muse, mutect2, varscan2
- ISLR | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV51434026; called by muse, mutect2, varscan2
- LRP1B | c.11331G>A p.M3777I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV101254031; called by muse, mutect2, varscan2
- LRP6 | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV53788343; called by muse, varscan2
- MAP3K5 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV62889504; called by muse, mutect2, varscan2
- MARK2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as COSV59283942; called by muse, mutect2
- MARK2 | c.887A>T p.E296V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59283964; called by muse, mutect2
- MAS1 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.934); catalogued as COSV53121301; called by muse, mutect2, varscan2
- MEGF8 | c.7826C>G p.S2609W (on ENST00000251268 / NM_001271938.2; = p.S2542W on NM_001410.3) | Missense Mutation (SNP) | VAF 54/65 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52087291, COSV99234802, COSV99238331; called by muse, mutect2, varscan2
- MOCS1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.823); catalogued as COSV57934408; called by muse, mutect2, varscan2
- MRTFA | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV62933652; called by muse, mutect2, varscan2
- MSH2 | c.174C>G p.F58L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372189599, COSV51880148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTHFR | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56740498; called by muse, mutect2, varscan2
- MTMR3 | c.1835G>C p.R612T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60305002; called by muse, mutect2, varscan2
- NAA60 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62654939; called by muse, mutect2, varscan2
- NAA60 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.497); catalogued as COSV62654954; called by muse, mutect2, varscan2
- NFATC2 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV65356805; called by muse, mutect2, varscan2
- NRXN3 | c.3236C>T p.S1079F (on ENST00000335750 / NM_001330195.2; = p.S706F on NM_004796.6) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59756500; called by muse, mutect2, varscan2
- NUP107 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV57495134; called by muse, mutect2, varscan2
- NYNRIN | c.5696G>T p.*1899Lext*109 | Nonstop Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV66842915; called by muse, mutect2, varscan2
- OXSR1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.946); catalogued as rs1311024425, COSV61258946; called by muse, mutect2, varscan2
- P2RY10 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs746304449, COSV50680309; called by mutect2, varscan2
- PCDH19 | c.1478T>C p.V493A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV55264316; called by muse, mutect2, varscan2
- PCNT | c.2489C>A p.S830* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV64028983; called by muse, mutect2, varscan2
- PCSK1 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60734011; called by muse, mutect2, varscan2
- PDIA4 | c.1516T>C p.F506L (on ENST00000286091 / NM_001371244.1; = p.F505L on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV53725010; called by muse, mutect2, varscan2
- PHF20L1 | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55193472; called by muse, mutect2
- PHKB | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV54523079; called by muse, mutect2, varscan2
- PINX1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV59109385; called by muse, mutect2, varscan2
- PLCL1 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs1439253243, COSV70836856; called by mutect2, varscan2
- PLXNA1 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.244); catalogued as rs577744672, COSV52527206; called by muse, mutect2, varscan2
- PNLDC1 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV51708327, COSV99277226; called by muse, mutect2, varscan2
- POLR1C | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs777698504, COSV54827519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 30/46 reads (65%) | catalogued as rs146650273; called by pindel, varscan2
- PXDNL | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV62488688; called by muse, mutect2, varscan2
- RSPH6A | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.687); catalogued as rs765728382, COSV55572338; called by muse, mutect2, varscan2
- SCN2A | c.488C>A p.T163K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51843329; called by mutect2, varscan2
- SCUBE1 | c.2212G>T p.E738* | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as COSV62612935; called by muse, mutect2, varscan2
- SEPHS2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV72100767; called by muse, mutect2, varscan2
- SLC27A4 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55960203; called by muse, mutect2, varscan2
- SLC37A1 | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61402626; called by muse, mutect2, varscan2
- SNAPC4 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV53733870; called by muse, mutect2, varscan2
- SON | c.1232C>G p.T411S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV51659548; called by muse, mutect2, varscan2
- SPIN3 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as rs760818671, COSV66528953; called by muse, mutect2, varscan2
- SPTA1 | c.7076A>G p.N2359S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV63754277; called by muse, mutect2, varscan2
- STK33 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); catalogued as COSV59402375; called by muse, mutect2, varscan2
- SUPT16H | c.2921-1G>C p.X974_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as COSV52850856; called by muse, mutect2, varscan2
- SYF2 | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs749059576, COSV52573632; called by muse, mutect2, varscan2
- SYNE3 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV62079898; called by muse, mutect2, varscan2
- TCEA2 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV58658454; called by muse, mutect2
- TCN2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs770055978, COSV53191247, COSV53191646; called by muse, mutect2, varscan2
- TMEM260 | c.1307T>C p.I436T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV55099939; called by muse, mutect2, varscan2
- TNK2 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs143850445, COSV100360813; called by muse, mutect2
- TOP3A | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV58177935; called by muse, mutect2, varscan2
- UBAP2 | c.3192C>G p.F1064L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54287823, COSV54289937; called by muse, mutect2, varscan2
- UCKL1 | c.1053C>G p.I351M | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62402987; called by muse, mutect2, varscan2
- UFSP1 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53818089; called by muse, mutect2
- USP51 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72351704; called by muse, mutect2, varscan2
- VPREB1 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100164821, COSV56425782; called by muse, mutect2
- VPS8 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54987270; called by muse, mutect2, varscan2
- ZBTB47 | c.1317G>C p.Q439H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs1403954469, COSV51764643; called by muse, mutect2, varscan2
- ZEB2 | c.1727A>G p.N576S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs748955225, COSV57957785; called by mutect2, varscan2
- ZNF440 | c.461G>C p.R154T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV58371314; called by muse, mutect2, varscan2
- ZNF611 | c.1531A>T p.K511* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV60541228; called by muse, mutect2, varscan2
- ZNF813 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV101124763, COSV67176702; called by muse, mutect2, varscan2
- ZNF883 | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV71309113; called by muse, mutect2, varscan2
- ARRDC3 | c.657C>A p.S219= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV54365416; called by muse, mutect2
- ATN1 | c.2826C>A p.L942= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV63111270; called by muse, mutect2, varscan2
- BAHD1 | c.252G>A p.R84= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV69084076; called by muse, mutect2, varscan2
- BRINP1 | c.1962C>T p.D654= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs750068438, COSV56301767; called by muse, mutect2, varscan2
- C1orf94 | c.1380C>G p.L460= (on ENST00000488417 / NM_001134734.2; = p.L270= on NM_032884.5) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV64914225; called by muse, mutect2, varscan2
- C21orf58 | c.411G>A p.L137= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV52449968; called by muse, mutect2, varscan2
- CCNE2 | c.747C>G p.L249= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100353659; called by muse, mutect2, varscan2
- CDC37 | c.69C>T p.I23= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1278107428, COSV55768571; called by muse, mutect2, varscan2
- CHRNB2 | c.1425C>T p.I475= | Silent (SNP) | VAF 41/156 reads (26%) | catalogued as rs773226966, COSV63808411; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRNG | c.768C>T p.S256= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV67315621, COSV67315972; called by muse, mutect2, varscan2
- CMTM5 | c.189G>A p.A63= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs570921659, COSV59305418; called by muse, mutect2, varscan2
- CROCC | c.3735G>A p.Q1245= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as COSV65012436; called by muse, mutect2, varscan2
- FCHO2 | c.864G>A p.K288= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV55108828; called by muse, mutect2, varscan2
- IFT81 | c.1617C>T p.L539= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs747127910, COSV54364303; called by muse, mutect2, varscan2
- KCNJ6 | c.603G>A p.E201= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV55715201; called by muse, mutect2, varscan2
- KCNQ1 | c.1650C>T p.L550= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV50110879; called by muse, mutect2, varscan2
- MC4R | c.6G>C p.V2= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100235904; called by muse, mutect2
- PLCL2 | c.1683G>A p.L561= (on ENST00000615277 / NM_001144382.2; = p.L435= on NM_015184.5) | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV67622568; called by muse, mutect2
- PTK6 | c.828C>T p.L276= | Silent (SNP) | VAF 65/96 reads (68%) | catalogued as COSV53917085; called by muse, mutect2, varscan2
- RAB40AL | c.645C>T p.P215= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV54434695; called by muse, mutect2, varscan2
- RELN | c.8802G>C p.V2934= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV59005908; called by muse, mutect2, varscan2
- SPNS2 | c.1560C>T p.L520= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs772518473, COSV54597564, COSV99625889; called by muse, mutect2
- TAGAP | c.1620G>A p.P540= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs200549687, COSV57852138; called by mutect2, varscan2
- ZNF773 | c.258G>T p.L86= | Silent (SNP) | VAF 17/151 reads (11%) | catalogued as COSV56588928; called by muse, mutect2, varscan2
- ZSCAN4 | c.45G>A p.E15= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1013004743, COSV59000060; called by muse, mutect2, varscan2
- C1orf220 | n.473C>T | RNA (SNP) | VAF 20/34 reads (59%) | catalogued as rs1048797491; called by muse, mutect2, varscan2
- MACF1 | c.15832-11568C>T | Intron (SNP) | VAF 13/23 reads (57%) | catalogued as COSV57124444; called by muse, mutect2, varscan2
- MACF1 | c.15832-10721C>T | Intron (SNP) | VAF 19/37 reads (51%) | catalogued as rs748156509, COSV57124460; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-66C>G | Intron (SNP) | VAF 8/27 reads (30%) | catalogued as COSV53581177, COSV68924465; called by muse, mutect2, varscan2
- PRR14L | chr22:31676976 C>T | 3'Flank (SNP) | VAF 42/109 reads (39%) | catalogued as rs1194216024; called by muse, mutect2, varscan2
- PTBP3 | chr9:112220173 C>G | 3'Flank (SNP) | VAF 9/28 reads (32%) | catalogued as rs758172640, COSV100534058, COSV100534077; called by muse, varscan2
- SSPOP | n.2777C>T | RNA (SNP) | VAF 5/16 reads (31%) | catalogued as rs1224847319, COSV50486280, COSV50487764; called by muse, mutect2, varscan2
